Gene-level copy-number profile of tumor specimen REBC-ACAE-TTP1-A from REBC case REBC-ACAE, project REBC-THYR (Comprehensive genomic characterization of radiation-related papillary thyroid cancer in the Ukraine). Sex at birth: female; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland.
Specimen REBC-ACAE-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c38ff59f-4fd8-4f36-ad66-da89b1e377c0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator REBC-ACAE-NT1-A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,228 have no estimate.
https://portal.gdc.cancer.gov/files/a3030779-fc51-412e-a851-2d5cecc0cf68

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 505; copy number 2: 57,786; copy number 3: 62; copy number 4: 7; copy number 5: 17; copy number 6: 4; copy number 7: 4; copy number 8: 1; copy number 9: 3; copy number 13: 2.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:18,333,726–18,419,273, 4 genes: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 30 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:195,003,711–195,026,370, 1 gene, copy number 7: AC010983.1.
- chr3:90,261,414–90,261,708, 1 gene, copy number 6: HSPE1P19.
- chr4:46,243,548–46,244,215, 1 gene, copy number 9: AC104072.1.
- chr5:86,353,803–86,368,854, 1 gene, copy number 8: AC016550.2.
- chr5:125,966,777–125,968,085, 1 gene, copy number 9: RPSAP37.
- chr5:155,491,336–155,493,598, 1 gene, copy number 9: AC008725.1.
- chr6:51,385,282–51,385,849, 1 gene, copy number 6: AL158050.2.
- chr7:62,275,361–62,275,678, 1 gene, copy number 6: AC128676.1.
- chr8:43,672,823–43,674,591, 2 genes, copy number 13: AC139365.2, AC139365.1.
- chr8:127,079,874–127,092,600, 1 gene, copy number 5 (within-gene range 2–5): PRNCR1.
- chr8:131,712,512–131,712,980, 1 gene, copy number 7: AC060788.1.
- chr9:40,883,634–40,883,763, 1 gene, copy number 7: AL353626.2.
- chr9:80,563,571–80,565,962, 2 genes, copy number 5: MTCO1P51, MTND2P9.
- chr10:108,940,969–108,941,310, 1 gene, copy number 6: RN7SKP278.
- chr11:54,591,480–54,725,816, 11 genes, copy number 5: OR4C50P, OR4C46, OR4C7P, OR4R2P, OR4A4P, OR4A3P, OR4A2P, OR4A8, OR4A7P, OR4A5, OR4A6P.
- chr11:59,391,354–59,392,292, 1 gene, copy number 7: OR5BB1P.
- chr12:91,327,045–91,368,607, 1 gene, copy number 5: LINC02823.
- chr16:52,198,012–52,227,956, 1 gene, copy number 5: AC007333.2.

Autosomal genes at a single copy (total copy number 1): 505. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
